Somatic mutation profile of tumor specimen TCGA-ET-A39K-01A (aliquot TCGA-ET-A39K-01A-11D-A19J-08) from TCGA case TCGA-ET-A39K, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 48.7 years (17,789 days).
Specimen TCGA-ET-A39K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10df868b-0ead-4d43-ae9c-e4db4aa2733d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A39K-10A (Blood Derived Normal), aliquot TCGA-ET-A39K-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a01dfc3c-e7df-4f58-9a5c-6f01b12ecb7a

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AHR | c.701T>A p.F234Y | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV54126714; called by muse, mutect2, varscan2
- ARFGEF2 | c.3747C>G p.C1249W | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV64215511; called by muse, mutect2, varscan2
- EFCAB7 | c.47C>A p.S16* | Nonsense Mutation (SNP) | VAF 11/110 reads (10%) | catalogued as COSV52135744; called by muse, mutect2, varscan2
- FAM47A | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV100650092, COSV60494022; called by muse, mutect2
- IFFO1 | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.585); catalogued as COSV59113887; called by muse, mutect2
- OSTC | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV64232547; called by muse, mutect2
- FLOT2 | c.918G>A p.V306= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV67529559; called by muse, mutect2
